Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3556, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3556-01A (Primary Tumor).

Diagnosis:

Resected section of colon (sigma) with a colon carcinoma of the histological type of a moderately differentiated, partially mucus-producing colorectal adenocarcinoma, measuring a maximum of 2 cm in diameter, and stretching up to 4.5cm to a margin of the resected material. The tumor has spread invasively to the internal sections of the muscularis propria.

Otherwise the intestinal wall has some pseudodiverticula and peridiverticulitis with chronic scarring.

Oral and aboral margin of the resected material is tumor-free.

22 mesocolic lymph nodes tumor-free with uncharacteristically reactive changes.

Tumor stage therefore pT2, pN0 (0/22) L0, V0; G2 R0.

Source: NCI Genomic Data Commons file 1d87ea8d-9ffe-4e90-9ac3-1bab5c71948c (TCGA-AA-3556.2DA209DB-A863-41A2-B387-265857A2DCE6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).